Gene-level copy-number profile of tumor specimen TCGA-CC-5264-01A from TCGA case TCGA-CC-5264, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 71.1 years (25,979 days).
Specimen TCGA-CC-5264-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.2b184e7a-eb66-417a-a8c8-e8fbd46ee99c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-5264-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9a75114-2006-4243-b515-08c44c552380

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 702; copy number 2: 19,442; copy number 3: 14,127; copy number 4: 13,109; copy number 5: 8,117; copy number 6: 3,475; copy number 7: 71; copy number 8: 730; copy number 14: 25; copy number 16: 12; copy number 20: 1; copy number 33: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-5264-01A-01D-A12Y-01): tumor purity 0.84, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:27,851,669–28,008,581, 6 genes (within-gene range 0–1): PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,935 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–60,100,200, 943 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:51,843,000–60,038,586, 142 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–51,428,427, 729 genes, copy number 8 (broad region; genes not listed).
- chr5:51,451,158–51,462,089, 1 gene, copy number 8: AC091860.2.
- chr7:70,972–159,233,377, 3,014 genes, copy number 5–6 (broad region; genes not listed).
- chr8:4,496,392–145,066,685, 2,419 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–57,513,425, 954 genes, copy number 5 (broad region; genes not listed).
- chr11:56,082,801–56,598,362, 45 genes, copy number 7–33: OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P.
- chr11:68,154,863–68,213,828, 1 gene, copy number 20 (within-gene range 2–20): KMT5B.
- chr11:68,707,440–71,670,297, 83 genes, copy number 6–16 (within-gene range 2–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 702. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
